Gene-level copy-number profile of tumor specimen ALCH-B05K-TTP1-A from ALCHEMIST case ALCH-B05K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 43.0 years (15,691 days).
Specimen ALCH-B05K-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aa559c2a-931b-4352-8662-3ce132c9cefd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B05K-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/4a4db369-bdc4-45e1-8157-a1316863cce2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 8,857; copy number 2: 34,174; copy number 3: 10,854; copy number 4: 4,071; copy number 5: 385; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:266,855–522,928, 9 genes: AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:235,565,761–235,566,937, 1 gene (within-gene range 0–2): FO393422.1.
- chr4:3,673,593–3,768,526, 3 genes: LINC02171, LINC02600, ADRA2C.
- chr5:180,601,506–180,649,624, 1 gene: FLT4.
- chr9:22,117,665–22,117,814, 1 gene (within-gene range 0–1): AL354709.2.
- chr9:136,249,973–136,306,901, 1 gene (within-gene range 0–1): CCDC187.
- chr9:136,322,303–136,373,681, 4 genes: DKFZP434A062, GPSM1, DNLZ, CARD9.
- chr13:27,953,526–27,969,315, 2 genes: LINC00543, CDX2.
- chr13:112,894,378–113,099,742, 5 genes: MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3.
- chr16:1,153,106–1,230,184, 7 genes (within-gene range 0–2): CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2.
- chr16:89,560,677–89,597,246, 3 genes: RPL13, SNORD68, CPNE7.
- chr17:81,976,807–82,098,294, 11 genes: ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN.
- chr19:17,323,223–17,342,731, 2 genes (within-gene range 0–2): ANO8, GTPBP3.
- chr22:29,711,820–29,731,833, 2 genes (within-gene range 0–3): AC004882.2, CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 387 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,228,319–2,391,707, 6 genes, copy number 5: SKI, AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2.
- chr14:28,765,640–52,552,522, 369 genes, copy number 5 (broad region; genes not listed).
- chr14:106,821,174–106,879,812, 10 genes, copy number 5: IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr17:47,323,290–47,441,312, 2 genes, copy number 6 (within-gene range 2–6): EFCAB13, AC040934.1.

Autosomal genes at a single copy (total copy number 1): 6,524. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
